Somatic mutation profile of tumor specimen ALCH-AD0E-TTP1-A (aliquot ALCH-AD0E-TTP1-A-1-0-D-A509-36) from ALCHEMIST case ALCH-AD0E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.7 years (24,371 days).
Specimen ALCH-AD0E-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccc7746b-b52f-4f86-820f-e30c943ada90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AD0E-NB1-A (Blood Derived Normal), aliquot ALCH-AD0E-NB1-A-1-0-D-A509-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85030348-78c0-4131-9be2-c8ff512f6c2b

The open-access MAF lists 67 somatic variants for this specimen: 52 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 12, Nonsense Mutation 4, In Frame Del 2, RNA 1, Splice Site 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 184/1335 reads (14%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- AGBL2 | c.1416G>T p.M472I | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100100985; called by muse, mutect2, varscan2
- CD247 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 66/1082 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.705); catalogued as rs757978223, COSV62977297; called by muse, mutect2
- COL14A1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 48/392 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs771290485, COSV52850061; called by muse, mutect2, varscan2
- CTNNA2 | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 93/928 reads (10%) | catalogued as COSV100781190, COSV63545002, COSV63606583; called by muse, mutect2, varscan2
- EBNA1BP2 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 45/483 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs1489078038, COSV52539122, COSV99356013; called by muse, mutect2
- FCHO1 | c.2380G>C p.V794L | Missense Mutation (SNP) | VAF 36/584 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV53181617; called by muse, mutect2
- H2BC5 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 25/392 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as rs1265576891, COSV56799921; called by muse, mutect2
- HUWE1 | c.11624C>T p.A3875V | Missense Mutation (SNP) | VAF 19/466 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1556916650, COSV53335320; called by muse, mutect2
- ID1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1223970977; called by muse, mutect2
- KCNQ1 | c.2017G>C p.D673H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); catalogued as rs866169644; called by muse, mutect2, varscan2
- MACO1 | c.1858G>A p.V620I | Missense Mutation (SNP) | VAF 35/537 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.766); catalogued as COSV65477285; called by muse, mutect2
- MROH6 | c.1504G>A p.V502I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1404385805; called by muse, mutect2, varscan2
- NLRP13 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 81/409 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs145312636; called by muse, mutect2, varscan2
- NOTCH4 | c.2791G>A p.V931M | Missense Mutation (SNP) | VAF 15/398 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as rs201560532; called by muse, mutect2
- OR7D4 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV58071525; called by muse, mutect2
- PKD1 | c.11978C>T p.S3993L (on ENST00000262304 / NM_001009944.3; = p.S3992L on NM_000296.4) | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as rs775512866, COSV51914083; called by muse, mutect2, varscan2
- RELL2 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 27/315 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149595207; called by muse, mutect2
- ST8SIA2 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 33/300 reads (11%) | PolyPhen probably damaging (0.998); catalogued as rs760014109; called by muse, mutect2, varscan2
- TARS3 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); catalogued as rs4555134; called by muse, mutect2, varscan2
- ARMH2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATPAF1 | c.453G>C p.E151D (on ENST00000574428; = p.E174D on NM_022745.4) | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.161); called by muse, mutect2
- BAZ2A | c.3440_3442del p.E1147del | In Frame Del (DEL) | VAF 28/211 reads (13%) | called by pindel, varscan2
- BRD1 | c.1785G>T p.E595D | Missense Mutation (SNP) | VAF 29/416 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- C12orf40 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- CFAP47 | c.9226G>T p.D3076Y | Missense Mutation (SNP) | VAF 89/599 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- COMP | c.2082C>A p.Y694* | Nonsense Mutation (SNP) | VAF 26/191 reads (14%) | called by muse, mutect2, varscan2
- CRYL1 | c.739+1G>A p.X247_splice | Splice Site (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- ECHDC2 | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- EME1 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 18/333 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.116); called by muse, mutect2
- FER1L5 | c.2276T>G p.L759R (on ENST00000623019; = p.L764R on NM_001293083.2) | Missense Mutation (SNP) | VAF 79/296 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KIAA2026 | c.4705C>T p.Q1569* | Nonsense Mutation (SNP) | VAF 49/299 reads (16%) | called by muse, mutect2, varscan2
- LRRCC1 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.923); called by muse, mutect2
- LTV1 | c.601A>C p.N201H | Missense Mutation (SNP) | VAF 22/701 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.329); called by muse, mutect2
- MAGEA8 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 13/302 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2
- MAGED2 | c.221A>G p.E74G | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2
- MAPT | c.1490C>T p.P497L (on ENST00000262410 / NM_001377265.1; = p.P422L on NM_016835.4) | Missense Mutation (SNP) | VAF 96/494 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MC3R | c.14G>A p.C5Y | Missense Mutation (SNP) | VAF 67/431 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MOB1A | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- MXI1 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NABP2 | c.282G>C p.K94N | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NPTX2 | c.497T>A p.L166Q | Missense Mutation (SNP) | VAF 34/650 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHGA9 | c.2273C>T p.S758F | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); called by muse, mutect2
- RGPD4 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 92/751 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- RNF13 | c.1022A>C p.Y341S | Missense Mutation (SNP) | VAF 112/512 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- SLC13A1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- SLC35A5 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 50/912 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.038); called by muse, mutect2
- TEX55 | c.198C>A p.S66R | Missense Mutation (SNP) | VAF 15/351 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- TRO | c.3462C>A p.S1154R | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2
- WDR4 | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- ZNF33A | c.1295G>C p.R432T (on ENST00000458705 / NM_006974.3; = p.R433T on NM_006954.2) | Missense Mutation (SNP) | VAF 42/401 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZZEF1 | c.8659A>G p.T2887A | Missense Mutation (SNP) | VAF 36/514 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.182); called by muse, mutect2
- ABCC10 | c.2055C>G p.L685= (on ENST00000372530 / NM_001198934.2; = p.L657= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/356 reads (11%) | called by muse, mutect2, varscan2
- AUTS2 | c.804C>T p.V268= | Silent (SNP) | VAF 120/555 reads (22%) | called by muse, mutect2, varscan2
- CLINT1 | c.648C>T p.I216= | Silent (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- DMRT3 | c.918G>A p.A306= | Silent (SNP) | VAF 13/328 reads (4%) | catalogued as COSV51903760; called by muse, mutect2
- FAM98C | c.933C>T p.N311= | Silent (SNP) | VAF 38/481 reads (8%) | catalogued as rs745545912, COSV53038483; called by muse, mutect2
- FLNA | c.5115C>T p.D1705= (on ENST00000369850 / NM_001110556.2; = p.D1697= on NM_001456.3) | Silent (SNP) | VAF 20/566 reads (4%) | catalogued as rs1032244227, COSV61037186; called by muse, mutect2
- GLG1 | c.153G>A p.G51= | Silent (SNP) | VAF 43/375 reads (11%) | called by muse, mutect2, varscan2
- NBEA | c.3918A>T p.G1306= | Silent (SNP) | VAF 18/486 reads (4%) | called by muse, mutect2
- PPM1H | c.171C>T p.S57= | Silent (SNP) | VAF 23/170 reads (14%) | called by muse, mutect2, varscan2
- RAB42 | c.126C>T p.F42= | Silent (SNP) | VAF 41/361 reads (11%) | catalogued as rs1295475429; called by muse, mutect2, varscan2
- TCEAL2 | c.540A>G p.K180= | Silent (SNP) | VAF 32/316 reads (10%) | catalogued as rs758670895; called by muse, mutect2, varscan2
- TP53BP2 | c.3291C>T p.D1097= (on ENST00000343537 / NM_001031685.3; = p.D968= on NM_005426.2) | Silent (SNP) | VAF 30/866 reads (3%) | catalogued as rs918543144; called by muse, mutect2
- KRT8P11 | n.905C>G | RNA (SNP) | VAF 17/546 reads (3%) | called by muse, mutect2
- PSENEN | chr19:35742496 G>A | 5'Flank (SNP) | VAF 34/581 reads (6%) | called by muse, mutect2
- WDR13 | c.41+68A>G | Intron (SNP) | VAF 24/162 reads (15%) | called by muse, mutect2, varscan2
